Somatic mutation profile of tumor specimen TCGA-CU-A3QU-01A (aliquot TCGA-CU-A3QU-01A-11D-A22Z-08) from TCGA case TCGA-CU-A3QU, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 58.1 years (21,233 days).
Specimen TCGA-CU-A3QU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05f4dd7a-bbc8-433b-8280-b1d2ff384831.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CU-A3QU-10B (Blood Derived Normal), aliquot TCGA-CU-A3QU-10B-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5159100a-a102-4c32-b273-d271d48969e3

The open-access MAF lists 105 somatic variants for this specimen: 72 protein-altering or splice-affecting, 33 silent.
By variant classification: Missense Mutation 60, Silent 33, Nonsense Mutation 7, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.1015A>G p.I339V | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.041); catalogued as COSV53327378; called by muse, mutect2, varscan2
- ACTA1 | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV64203914, COSV64204046; called by muse, mutect2, varscan2
- AL121899.2 | c.1463C>T p.T488M | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs771056380, COSV67352063; called by muse, mutect2, varscan2
- ALYREF | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs777282962, COSV58669033; called by muse, mutect2, varscan2
- ANKRD27 | c.1705C>G p.L569V | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV60135110; called by muse, mutect2, varscan2
- ARID4B | c.506T>C p.I169T | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs774237096, COSV51609411; called by muse, mutect2, varscan2
- ATP6AP1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs782271128, COSV63896163; called by muse, mutect2
- CAMSAP2 | c.3205G>A p.E1069K (on ENST00000236925 / NM_001297707.2; = p.E1058K on NM_203459.3) | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV52675820; called by muse, mutect2, varscan2
- CCNB3 | c.3670C>T p.R1224C | Missense Mutation (SNP) | VAF 48/51 reads (94%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs782145357, COSV52070254; called by muse, mutect2, varscan2
- CCR4 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs550719572, COSV58383472; called by muse, mutect2, varscan2
- CCT7 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV57823387; called by muse, mutect2, varscan2
- CDKN1A | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 24/40 reads (60%) | catalogued as COSV55186863; called by muse, mutect2, varscan2
- CHAMP1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 97/218 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs372508540, COSV63522272, COSV63523002; called by muse, mutect2, varscan2
- CRTC2 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV57845212; called by muse, mutect2, varscan2
- DCAF4L2 | c.114A>T p.R38S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772523773, COSV60481509; called by muse, mutect2, varscan2
- DCLK1 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55204216, COSV55218470; called by muse, mutect2, varscan2
- DNAH11 | c.9472G>C p.E3158Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60941383, COSV60974803; called by muse, mutect2, varscan2
- DNAH6 | c.2417T>C p.V806A | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV52878174; called by muse, mutect2, varscan2
- FAM210A | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV59185733; called by muse, mutect2, varscan2
- FANCI | c.3913G>A p.E1305K (on ENST00000310775 / NM_001376911.1; = p.E1245K on NM_018193.3) | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs773521811, COSV51524344; called by muse, mutect2, varscan2
- FBXW10 | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224175943, COSV57321267; called by muse, mutect2, varscan2
- FLNA | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as rs1160888270, COSV61049212; called by muse, mutect2, varscan2
- FPGT | c.591C>A p.D197E | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV63845358; called by muse, mutect2, varscan2
- FRYL | c.5043A>T p.K1681N | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.196); catalogued as COSV51958347; called by muse, mutect2, varscan2
- GRIA4 | c.1853T>C p.L618P | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56914436; called by muse, mutect2, varscan2
- GULP1 | c.704A>G p.N235S | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV63072432; called by muse, mutect2, varscan2
- IL23R | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV61375855; called by muse, mutect2, varscan2
- KCNH8 | c.458G>T p.R153I | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV60473736; called by muse, mutect2, varscan2
- KCNJ11 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs751772105, COSV60595303; called by muse, mutect2, varscan2
- KLHL24 | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV54428206; called by muse, varscan2
- KLHL24 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV54428214; called by muse, mutect2, varscan2
- LIMK1 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs782664768, COSV60279952; called by muse, mutect2, varscan2
- MAD2L1BP | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs1341177849, COSV64665648; called by muse, mutect2, varscan2
- MCF2L | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV100985146, COSV65098823; called by muse, mutect2, varscan2
- MFSD9 | c.379G>C p.G127R | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51495295, COSV99301876; called by muse, mutect2, varscan2
- MYO9A | c.6163G>C p.E2055Q | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV61855973; called by muse, mutect2, varscan2
- NEUROD4 | c.99G>C p.E33D | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV54473621; called by muse, mutect2, varscan2
- NHS | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 91/98 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1380680385, COSV66280668; called by muse, mutect2, varscan2
- OR2T11 | c.759C>G p.F253L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV58186909; called by muse, mutect2, varscan2
- PAIP1 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59087154; called by muse, mutect2, varscan2
- PGM1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1301021797, CM143004, COSV64301284; called by muse, mutect2, varscan2
- PIK3C2A | c.4502C>G p.A1501G | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as COSV56405917; called by muse, mutect2, varscan2
- PLEKHG4B | c.2152C>G p.H718D (on ENST00000283426; = p.H1074D on NM_052909.5) | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV52053257; called by muse, mutect2, varscan2
- POU2F1 | c.983G>A p.R328Q (on ENST00000541643 / NM_001365848.1; = p.R351Q on NM_002697.4) | Missense Mutation (SNP) | VAF 130/143 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV54820867, COSV54823258; called by muse, mutect2, varscan2
- RHBDL3 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52188452; called by muse, mutect2, varscan2
- RUSC2 | c.3713G>A p.G1238E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0.052); catalogued as COSV63429953; called by muse, mutect2, varscan2
- RXFP1 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57054936, COSV57057597; called by muse, mutect2, varscan2
- SH3BP5L | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 96/138 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs757664033, COSV63539758; called by muse, mutect2, varscan2
- SMC2 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT tolerated (0.43); PolyPhen benign (0.061); catalogued as COSV53963386; called by muse, mutect2, varscan2
- TM6SF1 | c.44C>G p.S15W | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.466); catalogued as rs780558833, COSV51945964, COSV51946706; called by muse, mutect2, varscan2
- TMEM245 | c.1101G>T p.Q367H | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65824161, COSV65824286; called by muse, mutect2, varscan2
- TNFRSF21 | c.1888G>C p.E630Q | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as COSV57281117, COSV57284525; called by muse, mutect2, varscan2
- TNRC6A | c.3713G>A p.R1238Q | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1280826015, COSV59368530; called by muse, mutect2, varscan2
- TOGARAM1 | c.425G>C p.R142P | Missense Mutation (SNP) | VAF 56/68 reads (82%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61889168, COSV61889199; called by muse, mutect2, varscan2
- TPO | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs751244187, COSV61108938; called by muse, mutect2, varscan2
- TSPEAR | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); catalogued as rs587714285, COSV59975349; called by muse, mutect2, varscan2
- TTC8 | c.385A>G p.I129V (on ENST00000338104 / NM_001288781.1; = p.I139V on NM_144596.4) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV57629652; called by muse, mutect2, varscan2
- VWCE | c.1789G>C p.D597H | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57114540; called by muse, mutect2, varscan2
- ZMYM4 | c.2125C>T p.Q709* | Nonsense Mutation (SNP) | VAF 35/109 reads (32%) | catalogued as COSV58907587; called by muse, mutect2, varscan2
- ZNF479 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.388); catalogued as COSV58642616; called by muse, mutect2
- ARAP2 | c.3627G>A p.W1209* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- ASXL1 | c.1690A>T p.K564* | Nonsense Mutation (SNP) | VAF 49/133 reads (37%) | called by muse, mutect2, varscan2
- CDKN1A | c.322dup p.E108Gfs*21 | Frame Shift Ins (INS) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- CYP7A1 | c.297del p.K99Nfs*27 | Frame Shift Del (DEL) | VAF 27/157 reads (17%) | called by mutect2, pindel, varscan2
- DAZL | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DCXR | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.09); called by muse, varscan2
- ELAPOR2 | c.931_942del p.P311_T314del (on ENST00000450689 / NM_001142749.3; = p.P144_T147del on NM_152748.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 42/119 reads (35%) | called by mutect2, pindel*, varscan2*
- FOLH1 | c.119-2A>C p.X40_splice | Splice Site (SNP) | VAF 10/95 reads (11%) | called by muse, varscan2
- PARD3 | c.2283_2296del p.E762Afs*9 | Frame Shift Del (DEL) | VAF 35/110 reads (32%) | called by mutect2, pindel, varscan2
- PIDD1 | c.1988_1996del p.F663_E666delins* | Nonsense Mutation (DEL) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- SLMAP | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 44/96 reads (46%) | called by muse, mutect2, varscan2
- VPS13D | c.2983G>T p.E995* | Nonsense Mutation (SNP) | VAF 117/190 reads (62%) | called by muse, mutect2, varscan2
- AC008397.2 | c.1458G>C p.L486= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as COSV53209008; called by muse, mutect2, varscan2
- ACCS | c.27C>T p.F9= | Silent (SNP) | VAF 40/76 reads (53%) | catalogued as COSV55459926; called by muse, mutect2, varscan2
- ALKBH7 | c.138G>A p.E46= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs1310305351; called by muse, mutect2, varscan2
- CANT1 | c.321C>T p.I107= | Silent (SNP) | VAF 117/253 reads (46%) | catalogued as rs775218418, COSV56606506; called by muse, mutect2, varscan2
- CFTR | c.1884G>A p.G628= | Silent (SNP) | VAF 53/117 reads (45%) | catalogued as COSV50085143; called by muse, mutect2, varscan2
- COX7B2 | c.39C>T p.L13= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV57221575; called by muse, mutect2, varscan2
- CSF2RA | c.615C>T p.F205= | Silent (SNP) | VAF 142/341 reads (42%) | catalogued as COSV62626327; called by muse, mutect2, varscan2
- EGFLAM | c.591G>A p.Q197= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as COSV59298340, COSV59313843; called by muse, mutect2, varscan2
- ERCC2 | c.547C>T p.L183= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV55543747; called by muse, mutect2, varscan2
- FN1 | c.4353G>A p.P1451= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs142628915; ClinVar: likely benign; called by muse, mutect2, varscan2
- GALNT18 | c.1203C>T p.N401= | Silent (SNP) | VAF 104/213 reads (49%) | catalogued as rs780730440, COSV57151314; called by muse, mutect2, varscan2
- HEXD | c.1460G>A p.*487= (on ENST00000327949 / NM_001369487.1; = p.E517K on NM_173620.3) | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as rs868416963, COSV60065507; called by muse, mutect2, varscan2
- HIF3A | c.1096C>A p.R366= (on ENST00000377670 / NM_152795.4; = p.R297= on NM_022462.4) | Silent (SNP) | VAF 47/89 reads (53%) | catalogued as COSV52203165; called by muse, mutect2, varscan2
- IFNA14 | c.186C>A p.P62= | Silent (SNP) | VAF 69/250 reads (28%) | catalogued as COSV66516388; called by muse, mutect2, varscan2
- IL18R1 | c.1542G>A p.K514= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV52126670; called by muse, mutect2, varscan2
- ITIH1 | c.561G>A p.V187= | Silent (SNP) | VAF 41/74 reads (55%) | catalogued as COSV56257796; called by muse, mutect2, varscan2
- KCNN2 | c.426C>T p.G142= (on ENST00000264773; = p.G354= on NM_021614.4) | Silent (SNP) | VAF 36/39 reads (92%) | catalogued as COSV53296760; called by muse, mutect2, varscan2
- KLHL24 | c.729G>C p.L243= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV54428199; called by muse, varscan2
- MAP3K14 | c.2070G>A p.P690= | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as rs748652165, COSV100766414; called by muse, mutect2, varscan2
- MED26 | c.249C>A p.L83= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV54662411; called by muse, mutect2, varscan2
- MTERF2 | c.423T>C p.F141= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV53528385, COSV99028179; called by muse, mutect2, varscan2
- NUF2 | c.1044G>A p.K348= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV54846243; called by muse, mutect2, varscan2
- PLXND1 | c.660C>T p.F220= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV60718149; called by muse, mutect2, varscan2
- PRAMEF2 | c.49C>T p.L17= | Silent (SNP) | VAF 112/193 reads (58%) | catalogued as COSV53578264; called by muse, mutect2, varscan2
- RABGGTA | c.15G>A p.L5= | Silent (SNP) | VAF 9/11 reads (82%) | catalogued as COSV53771429; called by muse, mutect2, varscan2
- RPAP2 | c.1383G>C p.L461= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs755854374, COSV72509173; called by muse, mutect2, varscan2
- SLC16A2 | c.1488C>T p.F496= | Silent (SNP) | VAF 53/60 reads (88%) | catalogued as rs1064797374, COSV52083080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC35C2 | c.891C>A p.L297= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV54758147; called by muse, mutect2, varscan2
- TACC1 | c.954C>G p.L318= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as rs61734982, COSV52527739; called by muse, mutect2, varscan2
- TECTA | c.1800C>T p.F600= | Silent (SNP) | VAF 46/94 reads (49%) | catalogued as COSV50777376; called by muse, mutect2, varscan2
- UNC13D | c.1410C>T p.F470= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs1296307278, COSV52884751; called by muse, mutect2, varscan2
- VWA1 | c.132C>T p.S44= | Silent (SNP) | VAF 45/91 reads (49%) | catalogued as rs370040804; called by muse, mutect2, varscan2
- WDR19 | c.2064C>T p.H688= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV56468942; called by muse, mutect2, varscan2
